Somatic mutation profile of tumor specimen TCGA-BR-8081-01A (aliquot TCGA-BR-8081-01A-11D-2340-08) from TCGA case TCGA-BR-8081, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 71.4 years (26,095 days).
Specimen TCGA-BR-8081-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ced5afe-252c-4ee8-8c40-33d6c9fd864a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8081-10A (Blood Derived Normal), aliquot TCGA-BR-8081-10A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/381b9ce3-5d64-4a8f-b7ab-45ad3ea68569

The open-access MAF lists 1,068 somatic variants for this specimen: 791 protein-altering or splice-affecting, 256 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 522, Silent 256, Frame Shift Del 169, Nonsense Mutation 39, Frame Shift Ins 33, Splice Site 11, Intron 10, In Frame Del 9, Splice Region 7, RNA 3, 3'Flank 2, 5'UTR 2.

Variants (750 of 1,068; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BMPR2 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as rs886041324, CM041256, CM146776, COSV65812812; ClinVar: pathogenic; called by muse, mutect2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 9/61 reads (15%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- DEPDC5 | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as rs1568991466, COSV56707538; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DGKE | c.610del p.T204Qfs*6 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as rs147972030; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2A | c.2318dup p.S774Vfs*12 | Frame Shift Ins (INS) | VAF 29/143 reads (20%) | catalogued as rs782297546; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 16/106 reads (15%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- PALB2 | c.839del p.N280Tfs*8 | Frame Shift Del (DEL) | VAF 15/122 reads (12%) | catalogued as rs1555461597; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 11/86 reads (13%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RAF1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs80338796, CM073301, COSV52574378, COSV52579821; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMCHD1 | c.1580C>T p.T527M | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs397518422, CM139374, COSV55263342; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPART | c.696del p.F232Lfs*2 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.902del p.P301Qfs*44 | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | catalogued as rs876660726, COSV53267099, COSV53486315; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TTN | c.34143dup p.P11382Tfs*4 (on ENST00000591111; = p.P10455Tfs*4 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 7/26 reads (27%) | catalogued as rs1198364572; ClinVar: likely pathogenic; called by mutect2, varscan2
- A2ML1 | c.509A>C p.Q170P | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55296958; called by muse, mutect2
- AASS | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs777979593, COSV62791389; called by muse, mutect2, varscan2
- ABCA4 | c.4004del p.P1335Qfs*54 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as CD1311148; called by mutect2, varscan2
- ABCE1 | c.1594G>A p.V532I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.738); catalogued as rs201425980, COSV56848671; called by muse, mutect2, varscan2
- ABHD15 | c.1052C>A p.P351H | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56196477; called by muse, mutect2, varscan2
- ABLIM1 | c.1015T>A p.S339T | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as COSV53313963; called by muse, mutect2, varscan2
- ACACB | c.7325G>A p.R2442Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs540153010, COSV58143588; called by muse, mutect2
- ACD | c.1408C>T p.P470S (on ENST00000620338; = p.P381S on NM_022914.3) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs746002676, COSV54669908; called by muse, mutect2, varscan2
- ACIN1 | c.3551G>T p.R1184L | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV52980844; called by muse, mutect2, varscan2
- ACTA1 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV64203934; called by muse, mutect2, varscan2
- ACTL9 | c.158T>A p.V53D | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61006914; called by muse, mutect2, varscan2
- ACTRT2 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs1336865916, COSV65760235; called by muse, mutect2, varscan2
- ACTRT3 | c.853G>T p.G285C | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV57755117; called by muse, mutect2, varscan2
- ADAMTS16 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1238198623, COSV56998924; called by muse, mutect2
- ADAMTS4 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs758269430, COSV63488502; called by muse, mutect2, varscan2
- ADCY1 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.149); catalogued as rs903105349, COSV52039695, COSV52040831; called by muse, mutect2, varscan2
- ADCY1 | c.2467C>T p.R823* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as rs61738404, COSV52035527; called by muse, mutect2, varscan2
- ADCY3 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs777689844, COSV53171677; called by muse, mutect2, varscan2
- ADCY6 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV57168480; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA3 | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV51567153; called by muse, mutect2, varscan2
- ADGRV1 | c.4604A>G p.E1535G | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV101316075; called by muse, mutect2
- ADH1A | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs781658187, COSV52925975; called by muse, mutect2, varscan2
- AHCTF1 | c.208C>T p.R70C (on ENST00000366508; = p.R44C on NM_015446.5) | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.042); catalogued as rs1307075702, COSV58253990; called by muse, mutect2
- AHNAK2 | c.7857G>T p.Q2619H | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV60927034; called by muse, mutect2, varscan2
- AHNAK2 | c.1976del p.K659Rfs*5 | Frame Shift Del (DEL) | VAF 28/228 reads (12%) | catalogued as rs1178630013; called by mutect2, pindel, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs778351035; called by mutect2, varscan2
- AKR1B15 | c.324G>A p.W108* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as COSV101423352, COSV71152664; called by muse, mutect2, varscan2
- AL035461.3 | c.2785C>T p.R929* | Nonsense Mutation (SNP) | VAF 9/118 reads (8%) | catalogued as rs771022882, COSV66652529, COSV66652782; called by muse, mutect2
- ALAS2 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs752853849, COSV58188274, COSV58190561; called by mutect2, varscan2
- ALAS2 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as COSV58192745; called by muse, mutect2, varscan2
- AMBRA1 | c.2887C>T p.R963* (on ENST00000458649 / NM_001367468.1; = p.R873* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as rs764989472, COSV54050338; called by muse, mutect2, varscan2
- ANK2 | c.7664C>T p.T2555I | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV52182691; called by muse, mutect2, varscan2
- ANK3 | c.6862A>G p.K2288E | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.45); catalogued as COSV55076843; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2117C>A p.P706H | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV51856151; called by muse, mutect2, varscan2
- ANKRD26 | c.4094A>G p.N1365S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV65777514; called by muse, mutect2, varscan2
- ANKS6 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV62051736; called by muse, mutect2
- ANO6 | c.2628G>T p.K876N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.392); catalogued as COSV57666592; called by muse, mutect2, varscan2
- ANXA2 | c.953A>T p.Y318F | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV60318420; called by muse, mutect2, varscan2
- AP002512.3 | c.402C>A p.F134L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs757096299, COSV54408427; called by muse, mutect2, varscan2
- AP1G1 | c.1931C>T p.A644V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs192683860, COSV55490215; called by muse, mutect2, varscan2
- AP5B1 | c.2438G>A p.R813H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1329771168, COSV57503922; called by muse, mutect2, varscan2
- APAF1 | c.2833C>T p.R945C (on ENST00000551964 / NM_181861.2; = p.R891C on NM_001160.3) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs774076296, COSV59667427; called by muse, mutect2, varscan2
- APC | c.6566A>G p.K2189R | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as rs986763235, COSV57372419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOE | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV52986172; called by mutect2, varscan2
- AQP5 | c.365T>G p.L122R | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV52231665; called by muse, mutect2, varscan2
- AREL1 | c.2392A>G p.T798A | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.356); catalogued as rs761880187, COSV62667777; called by muse, mutect2, varscan2
- ARHGAP20 | c.2351G>A p.G784D | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV52817598; called by muse, mutect2, varscan2
- ARHGAP25 | c.1203A>G p.T401= (on ENST00000409202 / NM_001007231.3; = p.T393= on NM_014882.3) | Splice Region (SNP) | VAF 16/134 reads (12%) | catalogued as COSV54907378; called by muse, mutect2, varscan2
- ARHGAP35 | c.3422G>A p.S1141N | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as rs1568468654, COSV68334771; called by muse, mutect2, varscan2
- ARHGAP36 | c.1546G>T p.G516* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV52269814; called by muse, mutect2, varscan2
- ARHGEF15 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV62726127; called by muse, mutect2, varscan2
- ARHGEF16 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as rs757295883, COSV65683067; called by muse, mutect2, varscan2
- ARHGEF2 | c.2806C>T p.R936W (on ENST00000361247 / NM_001162383.2; = p.R908W on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as rs751186042, COSV58115864; called by muse, mutect2, varscan2
- ARMC3 | c.164A>C p.K55T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53066255; called by muse, mutect2
- ARRDC1 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs146599172; called by muse, mutect2, varscan2
- ASAP3 | c.2536G>A p.V846I | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs753354426, COSV60877310; called by muse, mutect2, varscan2
- ASCC2 | c.713C>A p.P238H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV100316300; called by muse, mutect2
- ASPM | c.3301A>G p.R1101G | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.445); catalogued as COSV54136583; called by muse, mutect2, varscan2
- ASPN | c.201del p.P68Hfs*24 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | catalogued as rs778526424; called by mutect2, pindel, varscan2
- ATG2A | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as rs746748685, COSV65968466; called by muse, mutect2, varscan2
- ATM | c.4383G>T p.W1461C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53767284; called by muse, mutect2, varscan2
- ATMIN | c.2326G>A p.G776R | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as rs775731351, COSV55147286; called by muse, mutect2, varscan2
- ATP12A | c.2131del p.Q711Sfs*4 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | catalogued as rs1566077263; called by mutect2, varscan2
- ATP2A3 | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99989260, COSV99989342; called by muse, mutect2, varscan2
- AZIN1 | c.7G>T p.G3* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV61481036; called by muse, mutect2
- BAG3 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs876657747, COSV64842561; ClinVar: uncertain significance; called by muse, mutect2
- BCL6 | c.1649G>A p.R550H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.994); catalogued as rs147650939; called by muse, mutect2, varscan2
- BICD1 | c.451A>G p.R151G | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55686361; called by muse, mutect2, varscan2
- BICD1 | c.2365G>A p.A789T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200892811, COSV55686376; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | catalogued as rs772920507, COSV65808737; called by mutect2, varscan2
- BPTF | c.7749G>T p.Q2583H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV58844809; called by muse, mutect2, varscan2
- BRD4 | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as COSV54592840; called by muse, mutect2, varscan2
- BRPF1 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs199938433, COSV57407156; called by muse, mutect2, varscan2
- C11orf16 | c.66G>T p.K22N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV58168721; called by muse, varscan2
- C16orf86 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV54677350; called by muse, mutect2, varscan2
- C1orf50 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65308419; called by muse, mutect2, varscan2
- C1orf87 | c.441G>A p.W147* | Nonsense Mutation (SNP) | VAF 20/97 reads (21%) | catalogued as COSV64598396; called by muse, mutect2, varscan2
- C3 | c.4438T>C p.Y1480H | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55579716; called by muse, mutect2, varscan2
- C5orf34 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60931648; called by muse, mutect2, varscan2
- C7 | c.1118G>A p.G373E | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as rs923094633, COSV57480836; called by muse, mutect2, varscan2
- CACNA1D | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs144915770; called by muse, mutect2, varscan2
- CACNA1H | c.2918A>G p.Q973R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62000994; called by muse, mutect2, varscan2
- CACNA2D2 | c.3217_3219del p.K1073del (on ENST00000479441 / NM_001174051.3; = p.K1066del on NM_006030.4) | In Frame Del (DEL) | VAF 4/35 reads (11%) | catalogued as rs1381715737; called by mutect2, pindel
- CACNG6 | c.626del p.P209Rfs*21 (on ENST00000252729 / NM_145814.1; = p.P138Rfs*21 on NM_031897.2) | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | catalogued as rs745648688, COSV53168096; called by mutect2, varscan2
- CAD | c.4069G>A p.V1357I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs778120732, COSV53023783, COSV53030787; called by muse, mutect2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs745547658; called by mutect2, varscan2
- CASKIN2 | c.2182del p.Q728Rfs*74 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as rs751998890, COSV100051067; called by mutect2, varscan2
- CASP8AP2 | c.2479G>A p.A827T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV52749252; called by muse, mutect2, varscan2
- CCDC7 | c.2780C>T p.T927M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.284); catalogued as rs753507072, COSV56538185; called by muse, mutect2, varscan2
- CCDC87 | c.116del p.P39Rfs*15 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | catalogued as rs756825207, COSV59581359; called by mutect2, varscan2
- CCDC88C | c.3977G>A p.R1326H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs758005836, COSV66240895; called by muse, mutect2, varscan2
- CCDC90B | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs200672198, COSV52623356; called by muse, mutect2, varscan2
- CCL22 | c.185G>T p.R62M | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV54660626; called by muse, mutect2, varscan2
- CCNL2 | c.659+2T>C p.X220_splice | Splice Site (SNP) | VAF 14/106 reads (13%) | catalogued as COSV68767060; called by muse, mutect2, varscan2
- CCR2 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs200099906; called by muse, mutect2, varscan2
- CCR5 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV52752727; called by muse, mutect2, varscan2
- CD101 | c.1348A>G p.I450V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV56720456; called by muse, mutect2, varscan2
- CD46 | c.742T>C p.Y248H | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1167464505, COSV59735076; called by muse, mutect2
- CDC123 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs142243159; called by muse, mutect2, varscan2
- CDCA7 | c.485G>A p.R162H (on ENST00000347703 / NM_145810.3; = p.R241H on NM_031942.5) | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.871); catalogued as rs534928780, COSV60720163; called by muse, mutect2, varscan2
- CDH10 | c.1376T>G p.V459G | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs13174039, COSV52593699; called by muse, mutect2, varscan2
- CDH19 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs768597117, COSV50954841; called by muse, mutect2, varscan2
- CDH7 | c.1936A>G p.I646V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV59892579; called by muse, mutect2, varscan2
- CELSR3 | c.9532C>T p.R3178W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as rs758292109, COSV50873748; called by muse, mutect2, varscan2
- CEP126 | c.2812C>T p.P938S | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54825377; called by muse, mutect2, varscan2
- CERT1 | c.1318G>T p.G440C (on ENST00000405807 / NM_001130105.1; = p.G312C on NM_005713.3) | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54663424; called by muse, mutect2
- CFAP100 | c.1104del p.T369Rfs*36 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as rs747835123, COSV61504174; called by mutect2, pindel, varscan2
- CFAP206 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as rs768907065, COSV51533477; called by muse, mutect2, varscan2
- CHD4 | c.218del p.K73Rfs*129 | Frame Shift Del (DEL) | VAF 58/325 reads (18%) | catalogued as rs1322050057; called by mutect2, pindel, varscan2
- CHD9 | c.2949T>A p.C983* | Nonsense Mutation (SNP) | VAF 26/148 reads (18%) | catalogued as COSV54614972; called by muse, mutect2, varscan2
- CHRNA2 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV53559296; called by muse, mutect2, varscan2
- CHRNB1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs202080837, COSV53438818; called by muse, mutect2
- CHSY3 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59285733; called by muse, mutect2, varscan2
- CILK1 | c.1150T>C p.S384P | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV63155701; called by muse, varscan2
- CITED2 | c.251del p.P84Rfs*63 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | catalogued as rs748689446; called by mutect2, pindel, varscan2
- CLASRP | c.99+1G>A p.X33_splice | Splice Site (SNP) | VAF 3/12 reads (25%) | catalogued as COSV55512388; called by muse, mutect2
- CLCC1 | c.733G>A p.A245T (on ENST00000356970 / NM_001377464.1; = p.A195T on NM_015127.5) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370447874; called by muse, mutect2, varscan2
- CLIP1 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs748179509, COSV56807295; called by muse, mutect2, varscan2
- CLK2 | c.1405A>G p.T469A (on ENST00000368361 / NM_001294339.2; = p.T468A on NM_003993.4) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV56943808, COSV56947031; called by mutect2, varscan2
- CNIH2 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs1351510546, COSV61012184; called by muse, mutect2, varscan2
- CNKSR1 | c.1535dup p.P513Tfs*9 (on ENST00000374253 / NM_001297647.2; = p.P506Tfs*9 on NM_006314.3) | Frame Shift Ins (INS) | VAF 12/54 reads (22%) | catalogued as rs753922055; called by mutect2, varscan2
- CNNM1 | c.2557G>A p.E853K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as rs1231098786, COSV63201044; called by muse, mutect2, varscan2
- COL1A2 | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.129); catalogued as COSV51964240; called by muse, mutect2, varscan2
- COL24A1 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100994323, COSV65312297; called by muse, mutect2, varscan2
- COL4A6 | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | catalogued as COSV57874933; called by muse, mutect2
- COL5A2 | c.1790G>A p.G597D | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66413831; called by muse, mutect2, varscan2
- COL7A1 | c.4322del p.P1441Lfs*269 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | catalogued as rs753185460, CD993036, COSV60402854; called by mutect2, pindel, varscan2
- CPNE4 | c.901A>G p.M301V | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV70198959; called by muse, mutect2, varscan2
- CR1 | c.3103C>T p.H1035Y | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.121); catalogued as COSV65462102; called by muse, mutect2, varscan2
- CR2 | c.1810C>T p.H604Y | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV65509289; called by muse, mutect2, varscan2
- CREB3L4 | c.910del p.S304Pfs*29 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as COSV55131526; called by mutect2, pindel, varscan2
- CREBBP | c.4039C>T p.R1347W | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs867855180, COSV52127695; called by muse, mutect2, varscan2
- CREBBP | c.2438C>T p.P813L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs150767375; called by muse, mutect2, varscan2
- CRELD2 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV60304868; called by muse, mutect2
- CROT | c.102del p.K34Nfs*6 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs756999481; called by mutect2, pindel
- CSMD1 | c.2492G>A p.G831D (on ENST00000520002; = p.G830D on NM_033225.6) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59350330; called by muse, mutect2, varscan2
- CSMD2 | c.10337C>T p.A3446V | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.05); catalogued as COSV53950810; called by muse, mutect2, varscan2
- CSNK1G3 | c.145del p.I49Lfs*11 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | catalogued as rs775129818, COSV62054115, COSV62057434; called by mutect2, varscan2
- CTLA4 | c.168T>A p.F56L | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.024); catalogued as COSV55593016; called by muse, mutect2, varscan2
- CTNNAL1 | c.648A>T p.K216N | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57705025; called by muse, mutect2, varscan2
- CTPS2 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63723848; called by muse, mutect2, varscan2
- CTTN | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as COSV57235346; called by muse, mutect2, varscan2
- CTTNBP2 | c.926C>A p.T309K | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV50456573; called by muse, mutect2, varscan2
- CUBN | c.4130G>A p.R1377H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs139600855; called by muse, mutect2, varscan2
- CUL3 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52368963; called by muse, mutect2, varscan2
- CUL9 | c.2917C>T p.R973C | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs749921624, COSV52730712; called by muse, mutect2, varscan2
- CUX1 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs1554518441, COSV52911624; called by muse, mutect2, varscan2
- CXorf65 | c.4T>C p.F2L | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV52149876; called by muse, mutect2, varscan2
- CXorf66 | c.516del p.K172Nfs*2 | Frame Shift Del (DEL) | VAF 54/302 reads (18%) | catalogued as rs1288889313; called by mutect2, pindel, varscan2
- CYLD | c.1273A>G p.K425E | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.152); catalogued as rs1282444959, COSV61096974; called by muse, mutect2, varscan2
- CYP1B1 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs56175199, CM980504; called by muse, mutect2, varscan2
- CYP3A43 | c.752del p.N251Ifs*6 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as COSV55938439; called by mutect2, pindel, varscan2
- CYP4F3 | c.36G>A p.W12* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as COSV55412992; called by muse, mutect2, varscan2
- DAAM2 | c.3133C>T p.R1045C (on ENST00000274867 / NM_001201427.2; = p.R1044C on NM_015345.3) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs772498031, COSV51347345; called by muse, mutect2, varscan2
- DALRD3 | c.1510G>T p.G504W (on ENST00000341949 / NM_001009996.3; = p.G337W on NM_018114.5) | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58245182, COSV58247026; called by muse, mutect2, varscan2
- DCAF8L1 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); catalogued as rs1196316727, COSV71595139; called by muse, mutect2, varscan2
- DCC | c.2991G>A p.M997I | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV59127931; called by muse, mutect2, varscan2
- DDHD1 | c.873G>T p.M291I (on ENST00000323669; = p.M488I on NM_030637.3) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV60361930; called by muse, mutect2, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs772416332; called by mutect2, varscan2
- DENND3 | c.3286G>T p.G1096* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV99371070; called by muse, mutect2, varscan2
- DGKK | c.1519G>A p.V507I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs782135402, COSV65709161; called by muse, mutect2, varscan2
- DHRS7B | c.599G>A p.S200N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV100683922, COSV60888448; called by muse, mutect2, varscan2
- DICER1 | c.4024C>T p.R1342C | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs776854466, COSV58626266; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIDO1 | c.4217G>A p.R1406Q | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as COSV56631939; called by muse, mutect2, varscan2
- DIP2C | c.3214G>A p.V1072I | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.692); catalogued as rs756095859, COSV55174841; called by muse, mutect2, varscan2
- DIPK1B | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV65462633; called by muse, mutect2, varscan2
- DISP3 | c.2117G>A p.R706H | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs768466757, COSV53835354; called by muse, mutect2, varscan2
- DLC1 | c.2714A>C p.E905A (on ENST00000276297 / NM_001348081.2; = p.E468A on NM_006094.5) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.178); catalogued as COSV52322711; called by muse, mutect2, varscan2
- DLX3 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.363); catalogued as COSV71547881; called by muse, mutect2, varscan2
- DMD | c.6572G>A p.R2191Q | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs756238158, COSV58919631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMD | c.3401T>G p.L1134R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); catalogued as COSV63783587; called by muse, mutect2, varscan2
- DNAH9 | c.10192C>T p.R3398W | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200587417, COSV52370923; called by muse, mutect2, varscan2
- DNAJC27 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV53096458; called by muse, mutect2
- DOCK7 | c.1419del p.F473Lfs*8 | Frame Shift Del (DEL) | VAF 31/135 reads (23%) | catalogued as rs1557822062, COSV51995102; called by mutect2, pindel, varscan2
- DPP10 | c.1869A>C p.E623D | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV59715717; called by muse, mutect2, varscan2
- DPP8 | c.479G>A p.R160H (on ENST00000341861 / NM_001320875.2; = p.R144H on NM_017743.6) | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373358439, COSV55682381; called by muse, mutect2, varscan2
- DSCAM | c.5735A>G p.N1912S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.956); catalogued as COSV68033842; called by muse, mutect2, varscan2
- DVL2 | c.1801del p.A601Qfs*80 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as rs745455027; called by mutect2, varscan2
- EFEMP1 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs372748426; called by muse, mutect2, varscan2
- EFHB | c.303A>C p.K101N | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.145); catalogued as COSV55552352; called by muse, mutect2
- EGR2 | c.278T>C p.M93T | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.452); catalogued as rs200488421, COSV54348515; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 20/91 reads (22%) | catalogued as rs748937918; called by mutect2, varscan2
- ELFN2 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | catalogued as COSV68746133; called by muse, mutect2, varscan2
- ELP1 | c.3241C>A p.L1081I | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.27); catalogued as COSV65899442; called by muse, mutect2, varscan2
- ELP5 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372740494; called by muse, mutect2, varscan2
- ENO2 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.56); catalogued as COSV57545578; called by muse, mutect2, varscan2
- EPDR1 | c.158T>C p.V53A | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.437); catalogued as COSV52261522; called by muse, mutect2, varscan2
- EPHA1 | c.2044C>A p.H682N | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51975331; called by muse, mutect2
- EPPK1 | c.2335C>A p.L779M | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.106); catalogued as COSV73262282; called by muse, mutect2, varscan2
- EPSTI1 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771486075, COSV58048113; called by muse, mutect2, varscan2
- ERGIC3 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV53415064; called by muse, mutect2
- ERI3 | c.925G>A p.G309S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760730067, COSV64831766; called by mutect2, varscan2
- ETS1 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.555); catalogued as COSV60096708; called by muse, mutect2
- EVC2 | c.3145C>T p.Q1049* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV60400665; called by muse, mutect2
- EVI2B | c.593del p.N198Tfs*6 | Frame Shift Del (DEL) | VAF 27/129 reads (21%) | catalogued as rs765136869; called by mutect2, pindel, varscan2
- EXOC7 | c.1055-3del | Splice Region (DEL) | VAF 4/37 reads (11%) | catalogued as rs767353873; called by mutect2, pindel, varscan2
- EXOSC7 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs150001306; called by muse, mutect2, varscan2
- FAAH | c.1199G>A p.C400Y | Missense Mutation (SNP) | VAF 61/276 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as rs1305558155, COSV54545477; called by muse, varscan2
- FAM117B | c.1184A>C p.Q395P | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV57421493; called by muse, mutect2, varscan2
- FAM131A | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV55603571; called by muse, mutect2, varscan2
- FAM187B | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs372871240; called by muse, mutect2, varscan2
- FAM3D | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.653); catalogued as rs547933815, COSV62558184; called by muse, mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | catalogued as rs746983128; called by mutect2, varscan2
- FASTKD1 | c.962A>G p.E321G | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs766200089, COSV70007192; called by muse, mutect2, varscan2
- FASTKD3 | c.428del p.K143Rfs*36 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | catalogued as rs773607911, COSV52947201; called by pindel, varscan2
- FAT4 | c.11207del p.L3736Yfs*8 | Frame Shift Del (DEL) | VAF 28/154 reads (18%) | catalogued as rs1314412769; called by mutect2, pindel, varscan2
- FBF1 | c.454G>T p.G152* (on ENST00000586717; = p.G166* on NM_001319193.1) | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV59866560; called by muse, mutect2
- FBN3 | c.2259del p.G754Afs*23 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as COSV54456788; called by mutect2, pindel, varscan2
- FBRS | c.1333del p.R445Gfs*41 (on ENST00000287468; = p.R965Gfs*41 on NM_001105079.3) | Frame Shift Del (DEL) | VAF 16/97 reads (16%) | catalogued as COSV54916187; called by mutect2, pindel, varscan2
- FER1L5 | c.6057G>A p.P2019= (on ENST00000623019; = p.P1983= on NM_001293083.2) | Splice Region (SNP) | VAF 19/151 reads (13%) | catalogued as rs764358931, COSV53843542; called by muse, mutect2, varscan2
- FES | c.926+1G>A p.X309_splice | Splice Site (SNP) | VAF 23/103 reads (22%) | catalogued as rs1304018779, COSV60996092; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | catalogued as rs748969702; called by mutect2, varscan2
- FGD4 | c.1629G>T p.E543D | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV56788367; called by muse, mutect2, varscan2
- FHDC1 | c.2675G>A p.R892Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1346660307, COSV52602459; called by muse, mutect2, varscan2
- FLG | c.11183G>T p.G3728V | Missense Mutation (SNP) | VAF 55/293 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs745539898, COSV64246945; called by muse, mutect2, varscan2
- FMNL1 | c.2470G>A p.A824T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58958691; called by muse, mutect2, varscan2
- FOXD4L1 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 44/277 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs762583395, COSV52076166; called by muse, mutect2, varscan2
- FOXO4 | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV58576230; called by muse, mutect2, varscan2
- FRS2 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 16/88 reads (18%) | catalogued as rs1048144608, COSV54729019; called by muse, mutect2, varscan2
- GAL3ST2 | c.191G>A p.S64N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51951366; called by muse, mutect2, varscan2
- GALNT1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as COSV52454515; called by muse, mutect2, varscan2
- GALR2 | c.334A>G p.S112G | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57164333; called by muse, mutect2, varscan2
- GAS2L2 | c.2433del p.K812Rfs*5 | Frame Shift Del (DEL) | VAF 14/91 reads (15%) | catalogued as rs782288149; called by mutect2, pindel, varscan2
- GAS2L2 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555599598; called by muse, mutect2
- GDAP1 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.747); catalogued as rs753181104, COSV55186928; called by mutect2, varscan2
- GFM2 | c.1534C>T p.L512F | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV57192917; called by muse, mutect2, varscan2
- GGA3 | c.1814A>C p.N605T (on ENST00000537686 / NM_138619.4; = p.N572T on NM_014001.5) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV55458517; called by muse, mutect2, varscan2
- GGA3 | c.866T>C p.V289A (on ENST00000537686 / NM_138619.4; = p.V256A on NM_014001.5) | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.705); catalogued as COSV55458527; called by muse, varscan2
- GIGYF2 | c.3775C>T p.Q1259* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as COSV65252730; called by muse, mutect2, varscan2
- GIPR | c.868A>G p.N290D | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54425865; called by muse, mutect2, varscan2
- GLRA3 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56865940, COSV56868508; called by muse, mutect2, varscan2
- GNA11 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs144829732; called by muse, mutect2
- GNAQ | c.1035G>T p.K345N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV54122768; called by muse, varscan2
- GORASP2 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.009); catalogued as rs778067597, COSV52201913; called by muse, mutect2, varscan2
- GPATCH8 | c.223A>G p.K75E | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59197566; called by muse, mutect2
- GPKOW | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV50244804; called by muse, mutect2, varscan2
- GRAMD4 | c.249C>A p.H83Q | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.606); catalogued as COSV63032035; called by muse, mutect2, varscan2
- GREB1 | c.5773C>T p.R1925W | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755838573, COSV52179636; called by muse, mutect2, varscan2
- GRHL1 | c.1519C>A p.P507T | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV61410357; called by muse, mutect2, varscan2
- GRIA1 | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768255268, COSV53609656; called by muse, mutect2, varscan2
- GRIK4 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs373630796; called by muse, mutect2, varscan2
- GRIN2B | c.3895C>T p.R1299C | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs45540034, COSV74206883; called by muse, mutect2, varscan2
- GRPR | c.362T>C p.L121P | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66670105; called by muse, mutect2, varscan2
- GSTM3 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV56662942; called by muse, mutect2, varscan2
- GTF3C1 | c.3733C>T p.R1245C | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs772993464, COSV62238813; called by muse, mutect2, varscan2
- GTF3C3 | c.2075T>C p.M692T | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV99826744; called by muse, mutect2, varscan2
- GTF3C4 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.037); catalogued as COSV64645937; called by muse, mutect2, varscan2
- GYS1 | c.1325del p.P442Lfs*16 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs751494565, COSV54405555; called by mutect2, varscan2
- GZF1 | c.1678A>G p.N560D | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57637803; called by muse, mutect2, varscan2
- GZMA | c.542A>G p.D181G | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.865); catalogued as COSV57056242; called by muse, mutect2, varscan2
- H2BU1 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as rs1440490164, COSV64210111; called by muse, mutect2, varscan2
- H3C3 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.148); catalogued as COSV63551433; called by muse, mutect2, varscan2
- HCFC1 | c.680G>A p.C227Y | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as COSV60076525; called by muse, mutect2
- HDAC5 | c.1418C>T p.T473M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.764); catalogued as rs775955049, COSV56817548; called by muse, mutect2, varscan2
- HDAC6 | c.1499A>G p.H500R | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61930182; called by muse, mutect2, varscan2
- HELZ2 | c.3818G>A p.R1273Q (on ENST00000467148 / NM_001037335.2; = p.R704Q on NM_033405.3) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1341373290, COSV71296805; called by muse, mutect2, varscan2
- HERC1 | c.5780C>A p.P1927Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.996); catalogued as COSV101496610, COSV71249484; called by muse, mutect2, varscan2
- HIPK3 | c.1300dup p.C434Lfs*20 | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | catalogued as rs761758734; called by mutect2, varscan2
- HIPK3 | c.1756G>A p.G586R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.545); catalogued as rs140757794; called by muse, mutect2, varscan2
- HIVEP1 | c.4064A>G p.N1355S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.88); PolyPhen benign (0.042); catalogued as rs562910259, COSV65098866; called by muse, mutect2, varscan2
- HIVEP2 | c.4318C>T p.R1440* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV50039603; called by muse, mutect2, varscan2
- HLCS | c.1313C>A p.P438H | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60797154; called by muse, mutect2, varscan2
- HMGXB4 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV53335651; called by muse, mutect2
- HNRNPH1 | c.1319A>T p.N440I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV61487876; called by muse, mutect2, varscan2
- HOOK1 | c.1089del p.A364Qfs*8 | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | catalogued as COSV64619270; called by mutect2, pindel, varscan2
- HPDL | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.225); catalogued as COSV58344869; called by muse, mutect2, varscan2
- HSPA4L | c.830T>C p.M277T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56547856; called by muse, mutect2, varscan2
- HSPG2 | c.4876C>A p.R1626S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV65975956; called by muse, mutect2, varscan2
- IFIT2 | c.1190A>C p.E397A | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as COSV51080315; called by muse, mutect2, varscan2
- IGFALS | c.1346T>C p.L449P | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51907963; called by muse, mutect2, varscan2
- IGLV7-46 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs9619971; called by muse, mutect2, varscan2
- IGSF10 | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV56790522; called by muse, mutect2, varscan2
- IL10RA | c.1106A>C p.D369A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57141861; called by muse, mutect2, varscan2
- IL17RA | c.2231T>C p.V744A | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV60055675; called by muse, mutect2, varscan2
- ILDR1 | c.416A>G p.D139G | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56552993; called by muse, mutect2, varscan2
- INHA | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54728313, COSV54733219; called by muse, mutect2
- INPP4B | c.2452del p.R818Efs*4 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | catalogued as COSV53751800; called by mutect2, pindel, varscan2
- INTS1 | c.2527del p.R843Gfs*11 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs779930616; called by mutect2, varscan2
- INTS8 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV58252780; called by muse, mutect2, varscan2
- INTU | c.395del p.N132Ifs*11 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as rs771175764; called by mutect2, varscan2
- IPO9 | c.2440C>T p.H814Y | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.806); catalogued as COSV64235415; called by muse, mutect2, varscan2
- IRX1 | c.439A>G p.N147D | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV57361858; called by muse, mutect2, varscan2
- ISM2 | c.916T>C p.W306R | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV53636590; called by muse, mutect2, varscan2
- ITGA4 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201476802, COSV52003224; called by muse, mutect2, varscan2
- ITGB2 | c.1975G>A p.E659K (on ENST00000302347; = p.E635K on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs758504990, COSV56612630; called by muse, mutect2, varscan2
- ITGB4 | c.3865C>T p.R1289W | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs200409597, COSV52331349; called by muse, mutect2, varscan2
- ITPRID1 | c.2615C>T p.T872M | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as rs200617855, COSV60072097; called by muse, mutect2, varscan2
- ITSN2 | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61952702; called by muse, mutect2, varscan2
- IVD | c.973A>G p.M325V (on ENST00000651168; = p.M322V on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.432); catalogued as COSV51100680; called by muse, mutect2
- JHY | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs376060402, COSV57072578; called by muse, mutect2, varscan2
- JKAMP | c.166G>A p.A56T (on ENST00000554271 / NM_001284201.1; = p.A42T on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs1430847306, COSV54199339; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2382G>T p.W794C | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.394); catalogued as rs766967757, COSV58023564; called by muse, mutect2, varscan2
- KATNB1 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as rs782213832, COSV65551952; called by muse, mutect2, varscan2
- KCNH4 | c.642dup p.S215Vfs*39 | Frame Shift Ins (INS) | VAF 18/114 reads (16%) | catalogued as rs753954093; called by mutect2, varscan2
- KCNK9 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs1340677427, COSV57286527; called by muse, mutect2, varscan2
- KCNS2 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.174); catalogued as COSV54640445; called by muse, mutect2, varscan2
- KCTD15 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1182577391, COSV52291622; called by muse, varscan2
- KIAA1549 | c.4896del p.G1633Afs*78 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as COSV54314060; called by mutect2, pindel, varscan2
- KIAA1549L | c.1180G>T p.A394S (on ENST00000321505; = p.A691S on NM_012194.3) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV55779546; called by muse, mutect2, varscan2
- KIF1B | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV55814278; called by muse, mutect2, varscan2
- KIF26A | c.3355G>A p.V1119I | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs759574326, COSV59469832; called by muse, mutect2
- KIF7 | c.3870del p.E1291Rfs*3 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as COSV51538482; called by mutect2, pindel, varscan2
- KIN | c.1120-1G>T p.X374_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV101092455, COSV65431700; called by muse, mutect2, varscan2
- KIRREL3 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs771036286, COSV69385975; called by muse, mutect2, varscan2
- KL | c.973G>T p.G325C | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1000908514, COSV101199107; called by muse, mutect2
- KLC2 | c.1700del p.G567Afs*11 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as rs772643711; called by mutect2, varscan2
- KLHDC8B | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs753292522, COSV60412501; called by muse, mutect2, varscan2
- KMT2A | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV63291083; called by muse, mutect2, varscan2
- KPNA6 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65359610; called by muse, mutect2, varscan2
- KRTAP5-5 | c.432del p.S145Pfs*106 | Frame Shift Del (DEL) | VAF 16/84 reads (19%) | catalogued as rs1332581864; called by pindel, varscan2
- LAMA5 | c.7979G>T p.W2660L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV53369552; called by muse, mutect2, varscan2
- LCE1C | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs200121117, COSV64219089; called by muse, mutect2, varscan2
- LGALS3BP | c.338G>A p.C113Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53165831; called by muse, mutect2, varscan2
- LGALS9B | c.814C>T p.R272C (on ENST00000423676 / NM_001367292.1; = p.R271C on NM_001042685.2) | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs972585122, COSV60864300; called by muse, mutect2, varscan2
- LGR4 | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs761830490, COSV64865948; called by muse, mutect2, varscan2
- LINGO4 | c.1494G>A p.W498* | Nonsense Mutation (SNP) | VAF 30/198 reads (15%) | catalogued as COSV63216085; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs780042765; called by mutect2, varscan2
- LMO4 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.375); catalogued as rs149550347; called by muse, mutect2, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 9/83 reads (11%) | catalogued as rs748712732; called by mutect2, varscan2
- LOXL2 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs140591037; called by muse, mutect2, varscan2
- LOXL3 | c.824del p.G275Afs*5 | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | catalogued as rs746133895; called by mutect2, varscan2
- LRAT | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV60477946; called by muse, mutect2, varscan2
- LRP1 | c.9544G>A p.V3182I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs200382578, COSV54510023; called by muse, mutect2, varscan2
- LRP12 | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs748604344, COSV52628819; called by muse, mutect2, varscan2
- LRP3 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1197291462, COSV53505022; called by muse, mutect2
- LRP4 | c.4297C>A p.L1433M | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV66138079; called by muse, mutect2, varscan2
- LRRC32 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.545); catalogued as rs369688581; called by muse, mutect2, varscan2
- LRRC4 | c.1179C>A p.S393R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.028); catalogued as COSV99975027; called by muse, mutect2, varscan2
- LRRC8E | c.869C>T p.T290M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs781106170, COSV60719003; called by muse, mutect2, varscan2
- LRRIQ3 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63048766; called by muse, mutect2, varscan2
- LRRTM4 | c.275T>G p.L92R | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69139932, COSV69141009; called by muse, mutect2, varscan2
- LSM12 | c.235del p.L79* | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | catalogued as COSV99518678; called by mutect2, pindel, varscan2
- LTBP1 | c.3896A>G p.E1299G (on ENST00000404816 / NM_206943.4; = p.E973G on NM_000627.4) | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55384021; called by muse, mutect2
- MACF1 | c.19293+1G>A p.X6431_splice (on ENST00000372915; = p.X4476_splice on NM_012090.5) | Splice Site (SNP) | VAF 6/56 reads (11%) | catalogued as COSV57138854, COSV57140096; called by muse, mutect2
- MAGEE2 | c.133del p.Q45Sfs*27 | Frame Shift Del (DEL) | VAF 11/66 reads (17%) | catalogued as rs1159257962; called by mutect2, pindel, varscan2
- MAGI1 | c.4222G>A p.E1408K | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.288); catalogued as rs760749180, COSV58318545; called by muse, mutect2
- MAN1A1 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.326); catalogued as rs1403160997, COSV100870375; called by mutect2, varscan2
- MAP2 | c.5018T>A p.V1673D | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52304542; called by muse, mutect2, varscan2
- MAST4 | c.3736C>T p.R1246W (on ENST00000403625 / NM_001164664.2; = p.R1057W on NM_015183.3) | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55138234, COSV99846590; called by muse, mutect2, varscan2
- MAU2 | c.137T>C p.L46P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.845); catalogued as COSV53237755; called by muse, varscan2
- MBP | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); catalogued as COSV62829444; called by muse, mutect2, varscan2
- MC3R | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552943206, COSV54763275; called by muse, mutect2, varscan2
- MCM8 | c.2401C>T p.R801W | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.453); catalogued as rs147649536, COSV54511076; called by muse, mutect2, varscan2
- MDGA1 | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs774672732, COSV51800521; called by muse, mutect2, varscan2
- MDN1 | c.3093A>C p.K1031N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV65528493; called by muse, mutect2, varscan2
- MED12 | c.5305A>C p.T1769P | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV61352299; called by muse, mutect2
- MED22 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs782286256, COSV59299360; called by muse, mutect2
- MFAP5 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753225796, COSV100848202, COSV63945864; called by muse, mutect2, varscan2
- MFRP | c.275C>A p.P92H (on ENST00000449574; = p.P468H on NM_031433.4) | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV60991293; called by muse, mutect2
- MGAT1 | c.572G>A p.W191* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as COSV57135215; called by muse, mutect2, varscan2
- MGAT4B | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs146600579; called by muse, mutect2, varscan2
- MIA2 | c.1899A>T p.R633S | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV54499560; called by muse, mutect2, varscan2
- MID2 | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 25/130 reads (19%) | catalogued as COSV53313068; called by muse, mutect2, varscan2
- MIGA2 | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766886440, COSV52978280; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 24/116 reads (21%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MIS18BP1 | c.857A>G p.E286G | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV60373022; called by muse, mutect2, varscan2
- MLXIP | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59837483; called by muse, mutect2, varscan2
- MOS | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.516); catalogued as COSV61336868; called by muse, mutect2, varscan2
- MPDZ | c.3524G>A p.R1175Q | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201833535; called by muse, mutect2, varscan2
- MPND | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs377098672; called by muse, mutect2, varscan2
- MRGPRD | c.136A>C p.S46R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV58423273, COSV58423974; called by muse, mutect2, varscan2
- MSL3 | c.1319del p.P440Qfs*22 (on ENST00000312196 / NM_078629.4; = p.P274Qfs*22 on NM_006800.4) | Frame Shift Del (DEL) | VAF 22/170 reads (13%) | catalogued as rs768515139; called by mutect2, pindel, varscan2
- MSN | c.12+2T>C p.X4_splice | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as COSV64305208; called by muse, mutect2, varscan2
- MST1R | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs760389915, COSV56572702; called by muse, mutect2, varscan2
- MTA1 | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164967046, COSV58759745; called by muse, mutect2, varscan2
- MTG1 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58155027; called by muse, mutect2
- MTHFSD | c.247del p.T83Hfs*9 (on ENST00000360900 / NM_001159377.2; = p.T82Hfs*9 on NM_022764.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | catalogued as rs1266793672; called by mutect2, pindel
- MTMR4 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as rs375243165; called by muse, mutect2, varscan2
- MTUS2 | c.2134G>A p.G712R | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs552392007, COSV101462112, COSV70920456; called by muse, mutect2, varscan2
- MUC21 | c.1517T>G p.L506R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); catalogued as COSV66221938; called by muse, mutect2, varscan2
- MUC5B | c.11235G>T p.Q3745H | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV101500400; called by muse, mutect2, varscan2
- MUC6 | c.6258_6261del p.F2087Yfs*27 | Frame Shift Del (DEL) | VAF 20/117 reads (17%) | catalogued as rs779418838; called by pindel, varscan2
- MYBBP1A | c.2830C>T p.H944Y | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs772040831, COSV54598008; called by muse, mutect2, varscan2
- MYH1 | c.3418C>T p.R1140C | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1432611647, COSV56848015; called by muse, mutect2, varscan2
- MYH8 | c.5375C>T p.T1792M | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as rs144962215; called by muse, mutect2, varscan2
- MYL2 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.355); catalogued as rs727504559, COSV57407889; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK | c.2657C>T p.A886V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs140989388, COSV60612823; called by muse, mutect2, varscan2
- MYOM2 | c.3345A>C p.E1115D | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV50756462; called by muse, mutect2, varscan2
- NAA25 | c.1957C>T p.R653* | Nonsense Mutation (SNP) | VAF 37/207 reads (18%) | catalogued as rs757007450, COSV55705654; called by muse, mutect2, varscan2
- NCAM2 | c.2182C>T p.Q728* | Nonsense Mutation (SNP) | VAF 5/68 reads (7%) | catalogued as COSV53097506, COSV99525349; called by muse, mutect2
- NCAPD2 | c.2508del p.F837Sfs*36 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | catalogued as rs772347389; called by mutect2, pindel, varscan2
- NCDN | c.1417G>A p.V473I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs956053377, COSV61936878; called by muse, mutect2
- NCK2 | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768598254, COSV51895269; called by muse, mutect2, varscan2
- NCKAP1 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs887810579, COSV62943016; called by muse, mutect2, varscan2
- NEB | c.4847del p.K1616Rfs*19 | Frame Shift Del (DEL) | VAF 31/152 reads (20%) | catalogued as rs773640095; called by mutect2, pindel, varscan2
- NETO1 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 17/116 reads (15%) | catalogued as rs1051379392, COSV55013594; called by muse, mutect2, varscan2
- NEU3 | c.1268C>T p.T423I | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV53638549; called by muse, mutect2, varscan2
- NFKBIL1 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs200921108, COSV65990704; called by muse, mutect2, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 24/94 reads (26%) | catalogued as rs145147241; called by mutect2, varscan2
- NIT2 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs992981852, COSV67630155; called by muse, mutect2, varscan2
- NLGN2 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.033); catalogued as rs1385463579, COSV57211687; called by muse, mutect2, varscan2
- NLGN4X | c.1018T>A p.F340I | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52032788; called by muse, mutect2
- NOL11 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as COSV53525208; called by muse, mutect2, varscan2
- NOMO1 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55060905; called by muse, mutect2, varscan2
- NOX1 | c.449del p.K150Rfs*6 | Frame Shift Del (DEL) | VAF 42/319 reads (13%) | catalogued as COSV54192841; called by pindel, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs774343392; called by mutect2, varscan2
- NR2E1 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as COSV64561753; called by muse, mutect2, varscan2
- NTHL1 | c.719C>T p.T240M (on ENST00000219066; = p.T232M on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1308474938, COSV54593981; called by muse, mutect2
- NUAK1 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs747705556, COSV54607235; called by muse, mutect2, varscan2
- NUP88 | c.639A>G p.I213M | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV56707461; called by muse, mutect2
- NUP93 | c.1053G>A p.W351* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV100359878, COSV57433235; called by muse, mutect2, varscan2
- OBSCN | c.12332C>T p.A4111V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.146); catalogued as rs751764674, COSV52815635; called by muse, mutect2, varscan2
- ONECUT1 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs767975108, COSV59950547; called by muse, varscan2
- ONECUT1 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs746910544, COSV59948032; called by muse, varscan2
- OR10G4 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs755453278; called by mutect2, varscan2
- OR10Z1 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV63526119; called by muse, mutect2, varscan2
- OR11L1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs202119268, COSV63314778; called by muse, mutect2, varscan2
- OR1J4 | c.326A>G p.D109G | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV61590218; called by muse, mutect2, varscan2
- OR2G3 | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1349319775, COSV60682818, COSV60683201; called by muse, mutect2
- OR2L8 | c.404T>C p.M135T | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV61727983; called by muse, mutect2, varscan2
- OR2M7 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs183000679, COSV100522619, COSV58738570; called by muse, mutect2, varscan2
- OR2T12 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs771048088, COSV58775783; called by muse, mutect2, varscan2
- OR4K2 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV53851155; called by muse, mutect2, varscan2
- OR4Q3 | c.338T>G p.L113R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100057092, COSV59180403; called by muse, mutect2, varscan2
- OR51G1 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as rs750382799, COSV58969849; called by muse, varscan2
- OSBPL6 | c.2645G>A p.R882Q | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs767111652, COSV51916026; called by muse, mutect2, varscan2
- OSER1 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs750300001, COSV54854040; called by muse, mutect2, varscan2
- OTUD4 | c.3303_3305del p.R1102del (on ENST00000447906 / NM_001366057.1; = p.R1037del on NM_001102653.1) | In Frame Del (DEL) | VAF 18/156 reads (12%) | catalogued as rs750505087; called by pindel, varscan2
- P2RY8 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as COSV67178051; called by muse, mutect2, varscan2
- PADI3 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV64935196; called by muse, mutect2, varscan2
- PADI6 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.913); catalogued as COSV61885579; called by muse, mutect2, varscan2
- PBX1 | c.779A>G p.Y260C | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63342674, COSV63347531; called by muse, mutect2, varscan2
- PCDH10 | c.2853T>A p.D951E | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV52101892; called by muse, mutect2
- PCDH15 | c.4880C>T p.T1627I | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs763133029, COSV100226497, COSV57376391; called by muse, mutect2, varscan2
- PCDHA11 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as COSV56489775; called by muse, mutect2, varscan2
- PCDHGA8 | c.1538T>C p.V513A | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.367); catalogued as COSV54012100; called by muse, mutect2, varscan2
- PCDHGB5 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54012109; called by muse, mutect2, varscan2
- PCSK5 | c.2357A>G p.H786R | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV100950244, COSV65092631; called by muse, mutect2, varscan2
- PDCD11 | c.1990C>A p.L664I | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.115); catalogued as COSV63934995; called by muse, mutect2, varscan2
- PDZD2 | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs771417889, COSV56857649; called by muse, mutect2, varscan2
- PDZRN4 | c.2261G>A p.R754H (on ENST00000402685 / NM_001164595.2; = p.R496H on NM_013377.4) | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.97); catalogued as rs367580859, COSV54211224; called by muse, mutect2, varscan2
- PEAR1 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV52775295; called by muse, mutect2, varscan2
- PES1 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs376966812; called by muse, mutect2, varscan2
- PFKP | c.651G>T p.M217I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101127289; called by muse, mutect2, varscan2
- PHRF1 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs368390894; called by muse, mutect2, varscan2
- PIK3C2B | c.3680T>C p.I1227T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV65813679; called by muse, mutect2, varscan2
- PIK3C2B | c.2137C>T p.P713S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV100916143; called by muse, varscan2
- PIK3CD | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as rs373779625; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3R2 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs143821279; called by mutect2, varscan2
- PIK3R5 | c.1688G>A p.R563Q | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs267605109, COSV52657685; called by muse, mutect2
- PKD1 | c.5326C>A p.L1776M | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as COSV51923545; called by muse, mutect2, varscan2
- PKD1 | c.3127G>A p.V1043M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376890677; called by muse, mutect2, varscan2
- PKD1L1 | c.7403G>A p.S2468N | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.703); catalogued as COSV51844235; called by muse, mutect2
- PKD1L1 | c.1672del p.R558Dfs*10 | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | catalogued as rs897900295; called by mutect2, pindel, varscan2
- PLD3 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV62925701; called by muse, mutect2, varscan2
- PLD5 | c.1027G>A p.A343T (on ENST00000442594; = p.A281T on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs771246339, COSV59132452; called by muse, mutect2, varscan2
- PLEKHA7 | c.2405del p.F802Sfs*21 | Frame Shift Del (DEL) | VAF 24/128 reads (19%) | catalogued as rs1333390805, COSV63043367; called by mutect2, varscan2
- PLK4 | c.2260del p.S754Vfs*8 | Frame Shift Del (DEL) | VAF 16/98 reads (16%) | catalogued as rs1560699899; called by pindel, varscan2
- PLSCR4 | c.584G>A p.C195Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61608864; called by muse, mutect2, varscan2
- PLXNA2 | c.3317A>G p.Y1106C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.643); catalogued as COSV65444029; called by muse, mutect2, varscan2
- PLXNA3 | c.49del p.A17Pfs*12 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs782247826; called by mutect2, varscan2
- PLXNC1 | c.2982C>T p.D994= | Splice Region (SNP) | VAF 3/17 reads (18%) | catalogued as rs115290199; called by muse, mutect2
- PMS2 | c.1501G>A p.V501M | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs540287433, COSV56223549; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- PMS2 | c.476T>C p.V159A | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV56223553; called by muse, mutect2, varscan2
- PNMA8B | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 17/97 reads (18%) | catalogued as COSV66536133; called by muse, mutect2, varscan2
- PNMT | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs111272760; called by muse, mutect2, varscan2
- PNPLA3 | c.686dup p.D230Gfs*43 | Frame Shift Ins (INS) | VAF 9/90 reads (10%) | catalogued as rs1381775713; called by mutect2, pindel, varscan2
- POLE | c.5539_5541del p.K1847del | In Frame Del (DEL) | VAF 6/54 reads (11%) | catalogued as rs1060500844; called by pindel, varscan2
- POLG | c.2768G>A p.G923D | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM021663, COSV51524461; called by muse, mutect2, varscan2
- POLR3B | c.752T>C p.I251T | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV57283489; called by muse, mutect2, varscan2
- POP1 | c.2254del p.T752Lfs*12 | Frame Shift Del (DEL) | VAF 13/121 reads (11%) | catalogued as rs868622083, COSV62893071; called by mutect2, pindel
- PPIL2 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1279034844, COSV58605497; called by muse, mutect2, varscan2
- PPM1G | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as rs1466684553, COSV59768895; called by muse, mutect2, varscan2
- PPP2R2A | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs146354435; called by muse, mutect2
- PPP6R3 | c.1307G>A p.R436Q (on ENST00000393800 / NM_001352375.2; = p.R385Q on NM_018312.5) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs148673066; called by muse, mutect2, varscan2
- PQBP1 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs200715521, COSV54431231; called by muse, mutect2, varscan2
- PRAG1 | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs1177877580, COSV58165176; called by muse, mutect2, varscan2
- PRAME | c.545T>C p.F182S | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs200331967, COSV67162370; called by muse, mutect2, varscan2
- PRICKLE1 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as COSV58209793; called by muse, mutect2, varscan2
- PRKAR1B | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV64319707; called by muse, mutect2, varscan2
- PROZ | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs758194401, COSV61439000, COSV61440104; called by muse, mutect2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as rs753236928; called by mutect2, varscan2
- PRTG | c.3382C>T p.R1128W | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1020430872, COSV66840098; called by muse, mutect2, varscan2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PSMC3 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV54082358; called by muse, mutect2, varscan2
- PTGER2 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV55419899; called by muse, mutect2, varscan2
- PTPN13 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs948141302, COSV57409131; called by muse, mutect2, varscan2
- PTPRF | c.2620G>A p.D874N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs758580532, COSV63448034; called by muse, mutect2, varscan2
- PUM3 | c.779A>G p.N260S | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV67397252; called by muse, mutect2, varscan2
- PUS7 | c.774C>A p.C258* | Nonsense Mutation (SNP) | VAF 27/179 reads (15%) | catalogued as COSV62677911; called by muse, mutect2, varscan2
- PXDNL | c.3886C>A p.Q1296K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV62496467; called by muse, mutect2, varscan2
- PYGO2 | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.996); catalogued as COSV63756577, COSV63757477; called by muse, mutect2, varscan2
- RAB19 | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV52045777; called by muse, mutect2, varscan2
- RAB41 | c.123C>T p.S41= | Splice Region (SNP) | VAF 6/44 reads (14%) | catalogued as rs780258439, COSV52103984; called by mutect2, varscan2
- RAD17 | c.1204A>G p.K402E (on ENST00000380774 / NM_133339.2; = p.K391E on NM_002873.1) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51459195; called by muse, mutect2, varscan2
- RALGAPA2 | c.2754del p.S919Afs*24 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as COSV99173620; called by pindel, varscan2
- RALGAPB | c.4360C>T p.P1454S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as rs1430853518, COSV53439212; called by muse, mutect2, varscan2
- RALY | c.445C>T p.R149W (on ENST00000246194 / NM_016732.3; = p.R133W on NM_007367.4) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377184627, COSV55782782; called by muse, mutect2, varscan2
- RASAL2 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV62721173; called by muse, mutect2
- RBM12B | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 30/189 reads (16%) | catalogued as rs750295702, COSV67898720; called by muse, mutect2, varscan2
- RBPJL | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59215416; called by muse, mutect2, varscan2
- RELN | c.7033C>T p.P2345S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV59028416; called by muse, mutect2, varscan2
- RELT | c.1291T>C p.*431Rext*4 | Nonstop Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as COSV50359779; called by muse, mutect2, varscan2
- RGS3 | c.1156G>A p.G386R (on ENST00000350696 / NM_001282923.2; = p.G274R on NM_017790.4) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs749765337, COSV58284327; called by muse, mutect2, varscan2
- RHBDF2 | c.428G>A p.S143N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1471165635, COSV57422302; called by muse, mutect2, varscan2
- RHNO1 | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.147); catalogued as COSV100817050, COSV63485454; called by muse, mutect2, varscan2
- RHPN2 | c.957G>C p.E319D | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.676); catalogued as COSV54283525; called by muse, mutect2, varscan2
- RIOX1 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV58374633; called by muse, mutect2, varscan2
- RIPK1 | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV52531209; called by muse, mutect2, varscan2
- RNF213 | c.12511T>C p.Y4171H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV60406572; called by muse, mutect2, varscan2
- RNH1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs557604333, COSV62251499, COSV62251602; called by muse, mutect2, varscan2
- ROBO2 | c.3233del p.P1078Qfs*95 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | catalogued as rs745519558, COSV100168583; called by mutect2, varscan2
- RPE | c.519G>T p.E173D (on ENST00000359429 / NM_001318926.1; = p.E123D on NM_006916.2) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV55996242; called by muse, mutect2, varscan2
- RPS6KC1 | c.1061A>G p.D354G | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65302143; called by muse, mutect2, varscan2
- RRBP1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.937); catalogued as rs375344957; called by muse, mutect2, varscan2
- RRM2B | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.033); catalogued as CM1211106, COSV52566916, COSV52568260; called by muse, mutect2, varscan2
- RSF1 | c.1158del p.K386Nfs*6 | Frame Shift Del (DEL) | VAF 13/78 reads (17%) | catalogued as rs1451848162, COSV100408029; called by mutect2, pindel, varscan2
- RSRP1 | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV54563116; called by muse, mutect2, varscan2
- RTL8B | c.255G>T p.K85N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV66954410; called by muse, mutect2, varscan2
- RWDD2B | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as COSV54502101; called by muse, mutect2, varscan2
- RYR2 | c.2104G>T p.G702* | Nonsense Mutation (SNP) | VAF 11/77 reads (14%) | catalogued as COSV63707362; called by muse, mutect2, varscan2
- RYR2 | c.7303G>A p.V2435I | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.071); catalogued as rs188835713, COSV63687011; called by muse, mutect2, varscan2
- RYR2 | c.12045A>T p.K4015N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV63667138; called by muse, mutect2, varscan2
- S100A6 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV63297056; called by muse, mutect2
- S100A7A | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.209); catalogued as COSV61331159; called by muse, mutect2, varscan2
- SAMD9 | c.2240C>T p.A747V | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV66077177; called by muse, mutect2, varscan2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs763290832; called by mutect2, varscan2
- SBF1 | c.5023G>A p.A1675T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1255759968, COSV62369993; called by muse, mutect2, varscan2
- SBNO1 | c.3416del p.N1139Mfs*9 (on ENST00000420886; = p.N1138Mfs*9 on NM_018183.5) | Frame Shift Del (DEL) | VAF 22/123 reads (18%) | catalogued as rs765867975; called by mutect2, varscan2
- SCCPDH | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV63619162; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | catalogued as rs765136101; called by mutect2, pindel, varscan2
- SEC23IP | c.2614C>T p.Q872* | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | catalogued as COSV64832775; called by muse, mutect2, varscan2
- SEC61A1 | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.09); catalogued as COSV54576708; called by muse, mutect2
- SEH1L | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.718); catalogued as rs754300260, COSV50818086; called by muse, mutect2, varscan2
- SEMA6C | c.1721C>A p.A574D | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV59006722; called by muse, mutect2, varscan2
- SEMA6C | c.1432C>T p.R478W | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766594931, COSV59001420; called by muse, mutect2, varscan2
- SEMA7A | c.1993G>T p.V665F | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV56092042; called by muse, mutect2, varscan2
- SERPINA6 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs1166623585, COSV100448331, COSV58587023; called by muse, mutect2, varscan2
- SERPINB4 | c.586A>G p.K196E | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV61985982; called by muse, mutect2, varscan2
- SEZ6 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776212951, COSV57984042; called by muse, mutect2, varscan2
- SH3KBP1 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65640057; called by muse, mutect2, varscan2
- SHCBP1L | c.1810G>A p.V604I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs757649009, COSV62353893; called by muse, mutect2, varscan2
- SIN3B | c.1705G>A p.V569I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as rs371313884; called by muse, mutect2
- SLC12A3 | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs778585043, CM075011, COSV52638153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC14A2 | c.2485C>T p.Q829* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as rs151319242, COSV54913520; called by mutect2, varscan2
- SLC1A6 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.305); catalogued as rs756455637, COSV55673359; called by muse, mutect2, varscan2
- SLC25A44 | c.341T>C p.V114A | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as COSV63962249; called by muse, mutect2, varscan2
- SLC2A4 | c.34-1G>T p.X12_splice | Splice Site (SNP) | VAF 32/148 reads (22%) | catalogued as COSV58027506; called by muse, mutect2, varscan2
- SLC36A4 | c.71G>T p.R24M | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV100419387; called by muse, mutect2
- SLC6A15 | c.1451C>T p.T484M | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199711818; called by muse, mutect2, varscan2
- SLC6A3 | c.1300C>T p.L434F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV54368536; called by muse, mutect2, varscan2
- SLC7A3 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV53228370; called by muse, mutect2, varscan2
- SLC8A1 | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 23/145 reads (16%) | catalogued as COSV60493498; called by muse, mutect2, varscan2
- SLC9A3 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1327970675, COSV53804549; called by muse, mutect2, varscan2
- SLCO5A1 | c.1462C>A p.L488I | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.907); catalogued as COSV52666286; called by muse, mutect2, varscan2
- SLIT2 | c.1115T>C p.F372S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV56568444, COSV99884329; called by muse, mutect2, varscan2
- SMOC2 | c.799C>T p.R267C (on ENST00000356284 / NM_001166412.2; = p.R278C on NM_022138.3) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776824810, COSV62442832; called by muse, mutect2
- SMPD4 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs755218803, COSV60079083, COSV60081308; called by muse, mutect2, varscan2
- SMU1 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV101238543; called by muse, mutect2, varscan2
- SNAPC4 | c.4268C>A p.A1423D | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.483); catalogued as COSV53736653; called by muse, mutect2, varscan2
- SON | c.1628C>T p.T543M | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as rs755601747, COSV51659418; called by muse, mutect2, varscan2
- SOS2 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as rs756399613, COSV53570975; called by muse, mutect2
- SOX9 | c.916del p.V306Cfs*77 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as rs1297203260; called by mutect2, pindel
- SP110 | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 47/302 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.086); catalogued as rs140285393; called by muse, mutect2
- SPAG9 | c.1645del p.R549Gfs*28 (on ENST00000262013 / NM_001130528.3; = p.R535Gfs*28 on NM_003971.6) | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | catalogued as rs371303534; called by mutect2, varscan2
- SPATA17 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145142638; called by muse, mutect2, varscan2
- SPATA46 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62639129; called by muse, mutect2, varscan2
- SPDEF | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.249); catalogued as rs369097952; called by muse, mutect2, varscan2
- SPEG | c.8014G>A p.V2672M | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs773412903, COSV56671717; called by muse, mutect2, varscan2
- SPEN | c.6650C>T p.A2217V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs779675366, COSV65366472; called by muse, mutect2, varscan2
- SRPRA | c.1298C>T p.T433I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55008529; called by muse, mutect2, varscan2
- SSH2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs759933801, COSV52179390; called by muse, mutect2, varscan2
- SSU72P8 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.393); catalogued as rs782614965, COSV66361339; called by muse, mutect2, varscan2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | catalogued as rs747003550; called by mutect2, varscan2
- SYAP1 | c.963G>T p.Q321H | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66468653; called by muse, mutect2, varscan2
- SYNE2 | c.16514G>A p.R5505Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs552897930, COSV59965557; called by muse, mutect2, varscan2
- SYT3 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV58895472; called by muse, mutect2
- TACC2 | c.929G>A p.C310Y | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs773078761, COSV57768883; called by muse, mutect2, varscan2
- TASOR2 | c.1364C>A p.P455H | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV60169172; called by muse, mutect2, varscan2
- TBC1D4 | c.362A>G p.H121R | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.998); catalogued as COSV66491162; called by muse, mutect2
- TCEAL7 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV100197118; called by mutect2, varscan2
- TCHH | c.5641C>T p.R1881W | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as rs760165446, COSV64277198; called by muse, mutect2, varscan2
- TCTEX1D2 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57489202; called by muse, mutect2, varscan2
- TECTA | c.3619G>A p.V1207M | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.435); catalogued as rs746231346, COSV50694403, COSV50780342; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEKT3 | c.1190A>G p.Q397R | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV58629304; called by muse, mutect2, varscan2
- TENM1 | c.1319C>A p.S440Y | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV64427180; called by muse, mutect2, varscan2
- TENM3 | c.5672C>T p.A1891V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as rs1024115967, COSV69316445; called by muse, mutect2, varscan2
- TEPSIN | c.1350del p.G452Afs*72 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | catalogued as rs745976991, COSV56142035; called by pindel, varscan2
- TFIP11 | c.2032_2034del p.E678del | In Frame Del (DEL) | VAF 10/56 reads (18%) | catalogued as rs762805603; called by pindel, varscan2
- THAP12 | c.1415G>A p.S472N | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1267577776, COSV52612646; called by muse, mutect2, varscan2
- THAP3 | c.438+2T>C p.X146_splice (on ENST00000054650 / NM_001195753.1; = p.X153_splice on NM_138350.3) | Splice Site (SNP) | VAF 6/36 reads (17%) | catalogued as COSV50010884; called by muse, mutect2, varscan2
- TIAM2 | c.4261C>T p.R1421C (on ENST00000529824; = p.R1392C on NM_012454.3) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs754021821, COSV51643898; called by muse, mutect2, varscan2
- TJP3 | c.2545G>A p.V849M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs536563927, COSV53663774; called by muse, mutect2, varscan2
- TLN1 | c.3206C>T p.A1069V | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV59210844; called by muse, mutect2
- TLR10 | c.2256del p.A753Hfs*28 | Frame Shift Del (DEL) | VAF 11/89 reads (12%) | catalogued as rs564674109; called by mutect2, varscan2
- TLR10 | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV58301860; called by muse, mutect2, varscan2
- TMEM104 | c.433del p.V145Sfs*30 | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | catalogued as COSV100120983; called by mutect2, pindel, varscan2
- TMEM184A | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753024203, COSV52474466; called by muse, mutect2, varscan2
- TMEM25 | c.974_976del p.N325del | In Frame Del (DEL) | VAF 7/28 reads (25%) | catalogued as rs1555061837; called by pindel, varscan2
- TMEM268 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 15/89 reads (17%) | catalogued as rs781589029, COSV55986611; called by muse, mutect2, varscan2
- TMEM270 | c.707T>C p.V236A | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57638716; called by muse, mutect2, varscan2
- TMPO | c.1775C>A p.A592D | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV99702043; called by muse, mutect2
- TNS1 | c.1889C>A p.P630H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99410888; called by muse, varscan2
- TOM1L2 | c.385C>T p.R129* (on ENST00000379504 / NM_001350333.2; = p.R79* on NM_001033551.3) | Nonsense Mutation (SNP) | VAF 21/105 reads (20%) | catalogued as rs773862235, COSV58885179; called by muse, varscan2
- TPR | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1209080251, COSV66604120; called by muse, mutect2, varscan2
- TPTE | c.1285C>T p.R429C (on ENST00000618007 / NM_199261.4; = p.R411C on NM_199259.4) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs771783444; called by mutect2, varscan2
- TRANK1 | c.4743dup p.T1582Yfs*2 | Frame Shift Ins (INS) | VAF 6/32 reads (19%) | catalogued as rs1301850167; called by mutect2, pindel, varscan2
- TRIM26 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68963339; called by muse, mutect2, varscan2
- TRIM49 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769538739, COSV61670522; called by muse, mutect2, varscan2
- TROAP | c.1856C>A p.P619H | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV99226865; called by muse, varscan2
- TRPC7 | c.2540A>C p.K847T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as COSV61462365; called by muse, mutect2, varscan2
- TRPC7 | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1274493309, COSV61452394; called by muse, mutect2, varscan2
- TRPM3 | c.2314C>T p.R772C (on ENST00000357533 / NM_001366142.2; = p.R615C on NM_020952.6) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs747610777, COSV62586354; called by muse, mutect2, varscan2
- TRRAP | c.4473C>T p.N1491= | Splice Region (SNP) | VAF 4/36 reads (11%) | catalogued as rs1433592568, COSV62852337; called by muse, mutect2
- TSC2 | c.2431T>C p.C811R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54776264; called by muse, mutect2, varscan2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as rs760253164; called by mutect2, pindel, varscan2
- TTK | c.2560A>G p.R854G | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs755816263, COSV57881176, COSV57881188; called by muse, varscan2
- TTN | c.86927A>G p.Q28976R (on ENST00000591111; = p.Q21552R on NM_003319.4) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | PolyPhen benign (0.232); catalogued as rs769255050, COSV60279429; called by mutect2, varscan2
- TUBA3C | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.018); catalogued as COSV67139853; called by muse, mutect2
- TWNK | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752211501, COSV52971262; called by mutect2, varscan2
- UBL4A | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV54837157; called by muse, mutect2, varscan2
- UBR4 | c.8353G>T p.G2785C | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64396784; called by muse, mutect2, varscan2
- UPK2 | c.150del p.C51Vfs*10 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | catalogued as rs750952264; called by mutect2, pindel, varscan2
- UROC1 | c.161del p.P54Rfs*32 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | catalogued as rs764241328, COSV52031695; called by mutect2, pindel, varscan2
- USH2A | c.2782G>T p.G928* | Nonsense Mutation (SNP) | VAF 6/116 reads (5%) | catalogued as COSV56420606; called by muse, mutect2
- USHBP1 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.283); catalogued as rs755412167, COSV52243133; called by muse, mutect2, varscan2
- USP28 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50181271; called by muse, mutect2, varscan2
- VCPIP1 | c.1516A>G p.K506E | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.681); catalogued as COSV60049739; called by muse, mutect2, varscan2
- VEPH1 | c.1661del p.N554Tfs*5 | Frame Shift Del (DEL) | VAF 23/162 reads (14%) | catalogued as rs756863093; called by mutect2, varscan2
- VPS13A | c.1115del p.K372Sfs*2 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as rs770350986; called by mutect2, varscan2
- VPS13C | c.8165del p.N2722Tfs*27 (on ENST00000644861 / NM_020821.3; = p.N2679Tfs*27 on NM_017684.5) | Frame Shift Del (DEL) | VAF 9/69 reads (13%) | catalogued as COSV51425069; called by mutect2, pindel, varscan2
- VPS13D | c.9021+1G>A p.X3007_splice | Splice Site (SNP) | VAF 20/81 reads (25%) | catalogued as COSV50669819; called by muse, mutect2, varscan2
- VWF | c.5762G>A p.R1921Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs770879215, COSV54631401; called by muse, mutect2, varscan2
- WASL | c.1263dup p.V422Sfs*31 | Frame Shift Ins (INS) | VAF 12/66 reads (18%) | catalogued as rs1158703313; called by mutect2, varscan2
- WDR45 | c.695G>A p.R232H (on ENST00000376372 / NM_001029896.2; = p.R233H on NM_007075.3) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781978699, COSV59875449, COSV59875918; called by mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs746919573; called by mutect2, varscan2
- WNT16 | c.500del p.G167Afs*17 (on ENST00000222462 / NM_057168.2; = p.G157Afs*17 on NM_016087.2) | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | catalogued as rs771899177; called by mutect2, pindel, varscan2
- WWC3 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.336); catalogued as COSV66506348; called by muse, mutect2, varscan2
- XIRP2 | c.7030A>G p.I2344V (on ENST00000628543; = p.I2519V on NM_152381.6) | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV54727744; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | catalogued as rs762052135; called by mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs779864368; called by mutect2, varscan2
- YBX1 | c.821A>C p.Q274P | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV58439858; called by muse, mutect2
- YOD1 | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs751648828, COSV60006883; called by muse, mutect2, varscan2
- YTHDC1 | c.1742G>A p.R581Q (on ENST00000344157 / NM_001031732.4; = p.R563Q on NM_133370.4) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs769172184, COSV60011726; called by muse, mutect2, varscan2
- ZBTB9 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67702351; called by muse, mutect2, varscan2
- ZC3H12C | c.1919A>G p.Y640C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.97); catalogued as rs989678949, COSV53711937; called by muse, mutect2, varscan2
- ZC3H4 | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756950439, COSV53410194; called by muse, mutect2, varscan2
- ZFAND3 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs993407737, COSV54732559; called by muse, mutect2, varscan2
- ZFX | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as rs997542526, COSV58449549; called by muse, mutect2, varscan2
- ZIC1 | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.275); catalogued as rs764570223, COSV51556964; called by muse, mutect2, varscan2
- ZMYND11 | c.272A>G p.E91G | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV59079138; called by muse, mutect2, varscan2
- ZMYND15 | c.1684-1G>T p.X562_splice (on ENST00000433935 / NM_001136046.3; = p.X523_splice on NM_032265.2) | Splice Site (SNP) | VAF 26/110 reads (24%) | catalogued as COSV52644329; called by muse, mutect2, varscan2
- ZNF205 | c.1541G>A p.S514N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as COSV54622577; called by muse, mutect2
- ZNF280C | c.564dup p.P189Tfs*5 | Frame Shift Ins (INS) | VAF 20/80 reads (25%) | catalogued as rs770944520; called by mutect2, varscan2
- ZNF334 | c.1163G>A p.C388Y | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV61619812; called by muse, mutect2, varscan2
- ZNF334 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs774723342, COSV61618769; called by muse, mutect2, varscan2
- ZNF43 | c.752del p.N251Ifs*28 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as rs753886536; called by mutect2, varscan2
- ZNF48 | c.733del p.E245Sfs*47 | Frame Shift Del (DEL) | VAF 11/67 reads (16%) | catalogued as COSV100198003, COSV60783190; called by mutect2, pindel, varscan2
- ZNF518B | c.889C>A p.L297M | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV58724398; called by muse, mutect2, varscan2
- ZNF521 | c.977A>G p.Y326C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64129773; called by muse, mutect2, varscan2
- ZNF606 | c.1057A>G p.I353V | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.175); catalogued as rs766594065, COSV62048675; called by muse, mutect2, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 45/125 reads (36%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF629 | c.1543G>A p.V515M | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.469); catalogued as COSV52698817; called by muse, mutect2, varscan2
- ZNF638 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.991); catalogued as rs374546224; called by muse, mutect2, varscan2
- ZNF648 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV60569549; called by muse, mutect2, varscan2
- ZNF665 | c.1615G>A p.G539S (on ENST00000600412; = p.G604S on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV67216923; called by muse, mutect2, varscan2
- ZNF674 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs202006634, COSV70379653; called by muse, mutect2, varscan2
- ZNF692 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.837); catalogued as rs143513211, COSV60660035; called by muse, mutect2, varscan2
- ZNF76 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748068461, COSV57592517; called by muse, mutect2, varscan2
- ZNF800 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs775508686, COSV56178373; called by muse, mutect2, varscan2
- ZNF804B | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs759020919, COSV60825532; called by muse, mutect2, varscan2
- ACACA | c.6154G>A p.G2052S | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACACA | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- AFF3 | c.1560_1561del p.K521Gfs*22 | Frame Shift Del (DEL) | VAF 18/132 reads (14%) | called by pindel, varscan2
- AHDC1 | c.1758del p.K586Nfs*37 | Frame Shift Del (DEL) | VAF 9/77 reads (12%) | called by mutect2, varscan2
- AL592490.1 | c.1661dup p.L554Ffs*3 | Frame Shift Ins (INS) | VAF 27/122 reads (22%) | called by mutect2, pindel, varscan2
- ALPK1 | c.3151del p.W1051Gfs*36 | Frame Shift Del (DEL) | VAF 32/197 reads (16%) | called by mutect2, pindel, varscan2
- APPL2 | c.494_495del p.K165Rfs*44 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | called by mutect2, pindel, varscan2
- ARFGEF1 | c.1475del p.N492Mfs*28 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- ARHGAP17 | c.2432del p.P811Hfs*26 (on ENST00000289968 / NM_001006634.3; = p.P733Hfs*26 on NM_018054.6) | Frame Shift Del (DEL) | VAF 34/204 reads (17%) | called by mutect2, pindel, varscan2
- ARHGAP5 | c.2476dup p.R826Kfs*21 | Frame Shift Ins (INS) | VAF 13/112 reads (12%) | called by mutect2, pindel, varscan2
- ARID1B | c.5508del p.L1837* | Frame Shift Del (DEL) | VAF 13/82 reads (16%) | called by mutect2, pindel, varscan2
- ATXN7 | c.1998del p.M667Cfs*8 | Frame Shift Del (DEL) | VAF 20/98 reads (20%) | called by mutect2, pindel, varscan2
- BBS9 | c.626T>C p.V209A | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.644); called by muse, mutect2
- BTN2A2 | c.881del p.K294Rfs*56 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- BTNL3 | c.1199_1200dup p.S401Pfs*8 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | called by mutect2, varscan2
- C1R | c.688_689del p.P230* (on ENST00000536053 / NM_001354346.2; = p.P216* on NM_001733.7) | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- C2orf42 | c.1230del p.K410Nfs*38 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | called by mutect2, pindel, varscan2
- CARD10 | c.295G>C p.A99P | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2
- CASK | c.1663del p.M555Cfs*63 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel
- CCSAP | c.607_609del p.N203del | In Frame Del (DEL) | VAF 16/106 reads (15%) | called by mutect2, pindel, varscan2
- CEP164 | c.381del p.S129Vfs*9 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- CHD7 | c.7763del p.N2588Ifs*4 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- CHEK2 | c.1308del p.E437Kfs*20 (on ENST00000382580 / NM_001005735.2; = p.E394Kfs*20 on NM_007194.4) | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- CIAPIN1 | c.187_189del p.I63del | In Frame Del (DEL) | VAF 25/159 reads (16%) | called by pindel, varscan2
- CNIH1 | c.394del p.Y132Tfs*6 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- COL6A3 | c.4533del p.S1512Pfs*3 | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | called by mutect2, pindel, varscan2
- COLQ | c.554del p.K185Rfs*39 | Frame Shift Del (DEL) | VAF 19/140 reads (14%) | called by mutect2, pindel, varscan2
- COMP | c.961del p.V321Sfs*83 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel, varscan2
- CREBBP | c.2237dup p.M747Nfs*85 | Frame Shift Ins (INS) | VAF 9/70 reads (13%) | called by mutect2, pindel, varscan2
- CYB5B | c.347del p.N116Mfs*16 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | called by mutect2, pindel*
- CYB5R2 | c.20_21del p.E7Afs*8 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by pindel, varscan2
- DDX17 | c.488del p.G163Efs*20 | Frame Shift Del (DEL) | VAF 12/97 reads (12%) | called by mutect2, pindel, varscan2
- DDX39B | c.447del p.F149Lfs*13 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | called by mutect2, varscan2
- DHX16 | c.3097del p.I1033* | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel
- DNAH7 | c.1036_1037del p.K346Afs*6 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by pindel, varscan2
- DUSP9 | c.1074del p.Q359Rfs*77 | Frame Shift Del (DEL) | VAF 24/132 reads (18%) | called by mutect2, pindel, varscan2
- EDNRA | c.491del p.L164Cfs*38 | Frame Shift Del (DEL) | VAF 21/157 reads (13%) | called by mutect2, pindel, varscan2
- EVPL | c.4372_4374del p.E1458del | In Frame Del (DEL) | VAF 15/111 reads (14%) | called by mutect2, pindel, varscan2
- EXD3 | c.1520del p.P507Qfs*9 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- FAT3 | c.3588dup p.A1197Cfs*51 | Frame Shift Ins (INS) | VAF 9/29 reads (31%) | called by mutect2, varscan2
- FOXA3 | c.139A>G p.S47G | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.503); called by muse, mutect2
- HERC2 | c.11900del p.G3967Afs*24 | Frame Shift Del (DEL) | VAF 19/97 reads (20%) | called by mutect2, varscan2
- HIVEP2 | c.5562dup p.C1855Mfs*13 | Frame Shift Ins (INS) | VAF 27/151 reads (18%) | called by mutect2, pindel, varscan2
- HMCN1 | c.11798del p.N3933Mfs*3 | Frame Shift Del (DEL) | VAF 18/105 reads (17%) | called by mutect2, pindel, varscan2
- HSPG2 | c.7311del p.T2438Rfs*19 | Frame Shift Del (DEL) | VAF 16/83 reads (19%) | called by mutect2, pindel, varscan2
- ICAM5 | c.1790A>G p.E597G | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- IL16 | c.3635_3636del p.S1212Cfs*9 (on ENST00000302987 / NM_172217.5; = p.S511Cfs*9 on NM_004513.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/109 reads (13%) | called by pindel, varscan2
- IL17RE | c.774del p.K258Nfs*34 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- IPO4 | c.2369del p.P790Lfs*116 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | called by mutect2, pindel, varscan2
- KAT5 | c.213dup p.K72Qfs*9 | Frame Shift Ins (INS) | VAF 14/101 reads (14%) | called by mutect2, pindel, varscan2
- KIAA0232 | c.330dup p.Q111Tfs*12 | Frame Shift Ins (INS) | VAF 16/101 reads (16%) | called by mutect2, pindel, varscan2
- KLHL38 | c.286del p.E96Rfs*12 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- KMT2B | c.7995del p.H2665Qfs*73 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- LRRC41 | c.1034dup p.A346Sfs*5 | Frame Shift Ins (INS) | VAF 7/67 reads (10%) | called by mutect2, pindel, varscan2
- LZIC | c.562dup p.T188Nfs*11 | Frame Shift Ins (INS) | VAF 36/241 reads (15%) | called by mutect2, pindel, varscan2
- MAP7D1 | c.245del p.P82Rfs*51 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | called by mutect2, varscan2
- MAP7D3 | c.1086del p.E363Sfs*2 | Frame Shift Del (DEL) | VAF 21/111 reads (19%) | called by mutect2, pindel, varscan2
- MCAM | c.325dup p.Q109Pfs*45 | Frame Shift Ins (INS) | VAF 15/99 reads (15%) | called by mutect2, pindel, varscan2
- MORC4 | c.2028_2029del p.G677* | Frame Shift Del (DEL) | VAF 18/127 reads (14%) | called by pindel, varscan2
- MRC1 | c.4284_4285del p.Y1429Ffs*2 | Frame Shift Del (DEL) | VAF 40/371 reads (11%) | called by mutect2, varscan2
- MSLN | c.336del p.E113Rfs*65 | Frame Shift Del (DEL) | VAF 22/159 reads (14%) | called by mutect2, pindel, varscan2
- MUC5B | c.1236dup p.L413Afs*25 | Frame Shift Ins (INS) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- MYO3A | c.1588del p.Y530Tfs*13 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel
- NBEA | c.3362dup p.N1121Kfs*2 | Frame Shift Ins (INS) | VAF 10/29 reads (34%) | called by mutect2, varscan2
- NDC1 | c.506del p.F169Sfs*3 | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | called by mutect2, pindel, varscan2
- NEIL1 | c.570del p.F191Lfs*20 | Frame Shift Del (DEL) | VAF 19/86 reads (22%) | called by mutect2, pindel, varscan2
- NEIL3 | c.1731del p.F577Lfs*23 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel, varscan2
- NOP14 | c.2388_2389del p.H796Qfs*3 | Frame Shift Del (DEL) | VAF 19/145 reads (13%) | called by pindel, varscan2
- NYAP1 | c.545del p.P182Qfs*21 | Frame Shift Del (DEL) | VAF 15/112 reads (13%) | called by mutect2, pindel, varscan2
- OR14I1 | c.724del p.Q242Sfs*17 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | called by mutect2, pindel, varscan2
- ORC2 | c.1148-3del | Splice Region (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel, varscan2
- OXR1 | c.740del p.N247Mfs*22 (on ENST00000442977 / NM_001198532.1; = p.N246Mfs*22 on NM_018002.3) | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | called by mutect2, pindel, varscan2
- PALD1 | c.1900del p.R634Efs*61 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
318 further variants in this file (41 protein-altering or splice-affecting, 256 silent, 21 other) are not listed here.
